CCDI case PBBWXT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/5fa03bd9-e71c-4608-ac99-a0445ceeebe7

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Gastrointestinal stromal tumor, NOS: ICD-O-3 morphology code: 8936/1; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 17.4 years (6,343 days).

Biospecimens (3 samples)
- Sample 0DJKK9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJKKI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJKL4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
